Somatic mutation profile of tumor specimen TCGA-39-5035-01A (aliquot TCGA-39-5035-01A-01D-1441-08) from TCGA case TCGA-39-5035, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.2 years (26,383 days).
Specimen TCGA-39-5035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20348898-0274-475a-96c6-3ee40e20262c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5035-11A (Solid Tissue Normal), aliquot TCGA-39-5035-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3362cbb4-11d1-4d8f-a49c-5a136a9db0b7

The open-access MAF lists 159 somatic variants for this specimen: 119 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 39, Nonsense Mutation 5, Splice Site 3, 5'Flank 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACE2 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53027824; called by muse, mutect2, varscan2
- ADGRV1 | c.18634G>A p.D6212N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV67995890; called by muse, mutect2, varscan2
- AIPL1 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51509057; called by muse, mutect2, varscan2
- AIRE | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV99381459; called by muse, mutect2
- AMPD3 | c.1024G>A p.D342N (on ENST00000396553 / NM_001025389.2; = p.D351N on NM_000480.3) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV67332514; called by muse, mutect2, varscan2
- ANO8 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV50199898; called by muse, mutect2, varscan2
- ATXN7L1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1246648475, COSV59496240; called by muse, mutect2, varscan2
- BRINP2 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs768210254, COSV64176441; called by muse, mutect2, varscan2
- C12orf40 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as COSV61138032; called by muse, mutect2, varscan2
- C4BPA | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV65537738; called by muse, mutect2, varscan2
- C8A | c.776G>C p.S259T | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV63486598; called by muse, mutect2, varscan2
- CACNA1D | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55448618, COSV55465797; called by muse, mutect2, varscan2
- CASP14 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55665459, COSV55666814; called by muse, varscan2
- CBLB | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 89/327 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1432380285, COSV51437395; called by muse, mutect2, varscan2
- CCDC77 | c.1158G>C p.E386D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV53475534; called by muse, mutect2, varscan2
- CCT8L2 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV63463873, COSV63463977; called by muse, mutect2, varscan2
- CNGB1 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51907416; called by muse, varscan2
- COL14A1 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52869566; called by muse, mutect2, varscan2
- COL3A1 | c.798+2T>G p.X266_splice | Splice Site (SNP) | VAF 16/92 reads (17%) | catalogued as COSV58596825; called by muse, mutect2, varscan2
- CPEB3 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV56463501; called by muse, mutect2
- CST8 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55671842, COSV55672164; called by muse, mutect2, varscan2
- CTTNBP2 | c.3416A>C p.Q1139P | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV50479842; called by muse, mutect2, varscan2
- CYP4B1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV54726356; called by muse, mutect2, varscan2
- CYP4F12 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369172315; called by muse, mutect2, varscan2
- DLX4 | c.319G>T p.E107* (on ENST00000240306 / NM_138281.3; = p.E35* on NM_001934.3) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV53593093, COSV99537815; called by muse, mutect2, varscan2
- DNAH8 | c.1202G>T p.R401I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV59482106; called by muse, mutect2, varscan2
- DOCK11 | c.3828G>C p.Q1276H | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV52243730, COSV52248082; called by muse, mutect2, varscan2
- DSCAM | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV68036796; called by muse, mutect2, varscan2
- ERBB2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs370959592; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.1342A>G p.N448D (on ENST00000531901 / NM_001301013.1; = p.N442D on NM_004100.5) | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1198184114, COSV62061263; called by muse, mutect2, varscan2
- F9 | c.885T>G p.N295K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV54382501; called by muse, mutect2, varscan2
- FAT3 | c.6301A>T p.T2101S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.019); catalogued as COSV53177126; called by muse, mutect2, varscan2
- FCSK | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV55375903; called by muse, mutect2, varscan2
- FLG | c.5540C>T p.T1847M | Missense Mutation (SNP) | VAF 202/634 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs766634595, COSV64242677, COSV64244514; called by muse, varscan2
- FLT1 | c.2873A>G p.D958G | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV56743777; called by muse, mutect2, varscan2
- GALNT5 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs763869457, COSV52041527; called by muse, mutect2, varscan2
- GATD1 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV60592824, COSV60593601; called by muse, mutect2, varscan2
- GLUD2 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV60153249; called by muse, mutect2, varscan2
- GPBP1L1 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV51973525; called by muse, mutect2, varscan2
- GRK7 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV53825608; called by muse, varscan2
- GRK7 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53825619; called by muse, varscan2
- GRM7 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs758949941, COSV63172588; called by muse, mutect2, varscan2
- GSR | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.61); catalogued as COSV55323371; called by muse, mutect2, varscan2
- H1-4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1047740849, COSV56803600; called by muse, mutect2, varscan2
- H2AC21 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV58613274; called by muse, mutect2, varscan2
- HACD1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1346964047, COSV63517201; called by muse, mutect2, varscan2
- HLA-G | c.680G>C p.C227S | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64406919; called by muse, mutect2
- HNRNPH3 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV56263374; called by muse, mutect2
- HNRNPH3 | c.251+1G>T p.X84_splice | Splice Site (SNP) | VAF 29/102 reads (28%) | catalogued as COSV56263379; called by muse, varscan2
- HOOK2 | c.1130A>T p.Q377L | Missense Mutation (SNP) | VAF 249/364 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV53404151; called by muse, varscan2
- IFI44L | c.652A>C p.K218Q | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60729486; called by muse, mutect2, varscan2
- IQSEC3 | c.2053G>A p.G685S (on ENST00000538872 / NM_001170738.2; = p.G382S on NM_015232.1) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs965193182, COSV58291340; called by muse, mutect2, varscan2
- KCNA4 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV60256110; called by muse, mutect2, varscan2
- KCNG2 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60270522; called by muse, mutect2
- KDM1A | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as rs766849199, COSV63090583; called by muse, mutect2, varscan2
- KIAA0319L | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs770305152, COSV57848683; called by muse, mutect2, varscan2
- KLRB1 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV57590049, COSV57590462; called by muse, mutect2, varscan2
- LIX1L | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV63417302; called by muse, mutect2, varscan2
- LY9 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 39/148 reads (26%) | catalogued as COSV54434261, COSV54438180; called by muse, mutect2, varscan2
- MEF2A | c.937G>A p.V313M (on ENST00000557942 / NM_001319206.2; = p.V307M on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766432411, COSV57537548; called by muse, mutect2, varscan2
- MPP7 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61738402; called by muse, mutect2, varscan2
- MRGPRX4 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV58591816; called by muse, mutect2, varscan2
- MS4A1 | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100619441; called by muse, mutect2, varscan2
- MXRA5 | c.633T>A p.N211K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV54251468; called by muse, mutect2, varscan2
- MYO9B | c.1107G>C p.L369F | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.358); catalogued as COSV68282959; called by muse, mutect2, varscan2
- NCAPD2 | c.3584C>G p.S1195C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57522112; called by muse, varscan2
- NTSR1 | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV65139641; called by muse, mutect2, varscan2
- NUSAP1 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV52973413; called by muse, mutect2, varscan2
- OCA2 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.572); catalogued as rs552418165, COSV62339253, COSV62347333; called by muse, mutect2, varscan2
- OR2M5 | c.411A>C p.R137S | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs569710089, COSV63545970; called by muse, mutect2, varscan2
- OR56A4 | c.437C>G p.S146W | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs746095013, COSV58109498, COSV58111628, COSV58111777; called by muse, mutect2, varscan2
- PAOX | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374809; called by muse, mutect2, varscan2
- PARP8 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV55867216; called by muse, mutect2, varscan2
- PCDH15 | c.4834A>C p.T1612P | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV57398700; called by muse, mutect2, varscan2
- PEAK1 | c.3104C>G p.S1035C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV56938718, COSV56943656; called by muse, mutect2, varscan2
- PHF23 | c.349T>G p.S117A | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV50039827; called by muse, mutect2, varscan2
- PLEC | c.2320G>T p.E774* (on ENST00000322810 / NM_201380.4; = p.E664* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV59697517; called by muse, mutect2, varscan2
- PMCH | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV59676813; called by muse, mutect2, varscan2
- POLR3E | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV55403726; called by muse, mutect2
- PRAMEF4 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99340283; called by muse, mutect2, varscan2
- PRKCG | c.653C>G p.T218R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV54732754, COSV54733455; called by muse, mutect2, varscan2
- RELA | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58016148; called by muse, mutect2, varscan2
- RELCH | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV56892671; called by muse, mutect2, varscan2
- RFWD3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 73/299 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV63099478; called by muse, mutect2, varscan2
- RGS19 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58658478; called by muse, mutect2, varscan2
- RPA4 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61293380; called by muse, mutect2, varscan2
- SCN3B | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54801368; called by muse, mutect2, varscan2
- SCN7A | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV69274769; called by muse, mutect2, varscan2
- SCN8A | c.3064C>G p.H1022D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV100633959, COSV61984197, COSV61993456; called by muse, mutect2, varscan2
- SEC16B | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs376159757; called by muse, mutect2, varscan2
- SGIP1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 99/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766560453, COSV52779387; called by muse, mutect2, varscan2
- SGIP1 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52779397; called by muse, mutect2, varscan2
- SLC26A3 | c.936G>C p.R312S | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.098); catalogued as COSV60642851; called by muse, mutect2, varscan2
- SLF1 | c.2005A>G p.I669V | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs745692986, COSV54373843; called by muse, mutect2, varscan2
- SLX4 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs188729744, COSV53568919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOCS6 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1281177015, COSV67547218; called by muse, mutect2, varscan2
- SPAG17 | c.3808G>C p.E1270Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV60468987; called by muse, mutect2, varscan2
- SRBD1 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1212961358, COSV55405796; called by muse, mutect2, varscan2
- SSX7 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53341756; called by muse, mutect2, varscan2
- SYT14 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs1212421741, COSV55054587; called by muse, mutect2, varscan2
- TAF8 | c.828C>A p.N276K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV65897198; called by muse, mutect2
- TENM1 | c.7491G>A p.M2497I | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV64444078; called by muse, mutect2, varscan2
- THBS2 | c.1265C>A p.T422K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64682332; called by muse, mutect2
- TMEM181 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs759806891, COSV65564075, COSV65565458; called by muse, mutect2, varscan2
- TRPC5 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53303460; called by muse, mutect2, varscan2
- TRPV1 | c.2346A>T p.R782S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV51524908; called by muse, mutect2
- TTN | c.77143G>T p.G25715C (on ENST00000591111; = p.G18291C on NM_003319.4) | Missense Mutation (SNP) | VAF 68/236 reads (29%) | PolyPhen probably damaging (1); catalogued as COSV60363103; called by muse, mutect2, varscan2
- TTN | c.28785G>C p.L9595F (on ENST00000591111; = p.L8668F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | PolyPhen benign (0.006); catalogued as COSV60363131; called by muse, mutect2, varscan2
- VIM | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV56407881; called by muse, mutect2, varscan2
- WNK3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63616042; called by muse, mutect2, varscan2
- ZFHX3 | c.3557T>G p.L1186R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.085); catalogued as COSV51737200; called by muse, mutect2, varscan2
- ZFYVE16 | c.3871C>T p.H1291Y | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1379220096, COSV62018037; called by muse, mutect2, varscan2
- ZIM3 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV54144306, COSV54146883; called by muse, mutect2, varscan2
- ZMYM3 | c.2493G>C p.K831N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58740901; called by muse, mutect2
- ZNF454 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100195556, COSV60766790, COSV60769082; called by muse, mutect2, varscan2
- ZNF561 | c.240G>A p.V80= | Splice Region (SNP) | VAF 20/87 reads (23%) | catalogued as rs1469286958, COSV57178965, COSV57179247; called by mutect2, varscan2
- ZNF827 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65225852, COSV65232291; called by muse, mutect2, varscan2
- TRGV2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCF3 | c.1045C>T p.L349= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs941231948, COSV53054756; called by muse, mutect2
- AFDN | c.2682C>T p.I894= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as rs373339327; called by muse, mutect2, varscan2
- ALDH4A1 | c.306C>G p.L102= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV51896260; called by muse, mutect2, varscan2
- ANKRD12 | c.1263C>G p.V421= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as COSV50819068, COSV50850966; called by muse, mutect2, varscan2
- ARHGAP31 | c.1449G>A p.A483= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV51793109; called by muse, mutect2, varscan2
- BMP5 | c.228T>G p.S76= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as COSV63706713; called by muse, mutect2, varscan2
- CDHR2 | c.1191C>T p.D397= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56145766; called by muse, mutect2, varscan2
- CTNND1 | c.2103C>T p.Y701= (on ENST00000399050 / NM_001085458.2; = p.Y695= on NM_001331.3) | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs762262057, COSV62386388; called by muse, mutect2, varscan2
- DSP | c.1764A>G p.Q588= | Silent (SNP) | VAF 99/258 reads (38%) | catalogued as rs1437385753, COSV65796297; called by muse, mutect2, varscan2
- DTX3L | c.913C>T p.L305= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV56145654; called by muse, mutect2, varscan2
- EEF1AKNMT | c.942C>G p.L314= (on ENST00000361735 / NM_015935.5; = p.L228= on NM_014955.3) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV62283870; called by muse, mutect2, varscan2
- EIF4G1 | c.549A>T p.R183= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as COSV59994302; called by muse, mutect2, varscan2
- FNDC7 | c.1548A>G p.S516= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99601799; called by muse, mutect2, varscan2
- HCN4 | c.2451C>T p.L817= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1167668657; called by muse, mutect2
- IRAG2 | c.3435G>A p.L1145= (on ENST00000636465; = p.L190= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV63140948; called by muse, mutect2, varscan2
- KANK3 | c.2112C>T p.I704= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs1015110048, COSV56847650; called by muse, mutect2, varscan2
- KDR | c.3273T>C p.F1091= | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as rs150647161; called by muse, mutect2, varscan2
- KIF4A | c.2265C>T p.V755= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV63285190; called by muse, mutect2, varscan2
- LAMA5 | c.7068G>C p.L2356= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV53373065; called by muse, mutect2, varscan2
- LAMA5 | c.6987G>A p.R2329= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV53373072; called by muse, mutect2, varscan2
- MROH2B | c.4719C>T p.T1573= | Silent (SNP) | VAF 318/542 reads (59%) | catalogued as COSV68189748; called by muse, mutect2, varscan2
- NALCN | c.2265C>T p.S755= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as rs757549395, COSV51955792; called by muse, mutect2, varscan2
- NKPD1 | c.1332G>A p.L444= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV58730340; called by muse, mutect2
- PCDHA1 | c.2139C>G p.L713= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV65372808, COSV65377101; called by muse, mutect2, varscan2
- PCDHB14 | c.1524G>C p.A508= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV53386426, COSV53391427; called by muse, mutect2, varscan2
- PHACTR3 | c.1492C>T p.L498= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV63034620; called by muse, mutect2, varscan2
- PIWIL1 | c.1515T>C p.Y505= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs748410507, COSV55352242; called by muse, mutect2, varscan2
- PKHD1 | c.10320C>G p.V3440= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV64400748; called by muse, mutect2, varscan2
- PPA1 | c.624A>T p.A208= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as COSV64684568; called by muse, mutect2, varscan2
- RTL4 | c.894T>G p.S298= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV61207382; called by muse, mutect2
- SFMBT2 | c.333C>T p.Y111= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs113302721, COSV62805435; called by muse, mutect2, varscan2
- TECTA | c.4494C>T p.F1498= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs374996667, COSV50704462; called by muse, mutect2, varscan2
- TLN2 | c.5877G>C p.T1959= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60890569, COSV60896135; called by muse, mutect2, varscan2
- TNFAIP3 | c.282G>C p.A94= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV52802487; called by muse, mutect2, varscan2
- TPR | c.4110A>G p.Q1370= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs756247748, COSV66605227; called by muse, mutect2, varscan2
- UBE2C | c.300G>A p.T100= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs1568716123, COSV54755640; called by muse, mutect2, varscan2
- VIM | c.1284G>T p.L428= | Silent (SNP) | VAF 72/285 reads (25%) | catalogued as COSV56407870; called by muse, mutect2, varscan2
- XIRP1 | c.2536C>T p.L846= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV61141518; called by muse, mutect2, varscan2
- YIPF3 | c.874C>T p.L292= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV58307221; called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106390 T>C | 5'Flank (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100836928; called by muse, mutect2, varscan2
